CCDI case PBCGSK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/3d29be38-a9d7-4be7-94c5-7595f257db8c

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 12.9 years (4,701 days).

Biospecimens (3 samples)
- Sample 0DRVOJ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRVOQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRVOZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
